Surgical pathology report (de-identified scan), TCGA case TCGA-66-2753, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2753-01A (Primary Tumor).

[page 1 of 2]
Examination report

Macroscopic findings:

1. Parietal pleura: excised material, one with a diameter of max. 5 and one with a diameter of 4 mm.
2. (a-i) Left inferior pulmonary lobe: resected lobe weighing 277 g and measuring 180 x 120 x 70 mm with moderate mesh-like anthracosis of the pleura, hilar staple sutures and an exposed bronchial stump measuring just under 10 mm. Next to this, individual, swollen lymph nodes with anthracotic pigment but no suspicion of a tumor. In S 6 there is grayish-white tumor infiltration, well-demarcated around the edge, measuring a good 40 mm, extending up to the outer pleura, with central, post-necrotic-pseudocystic resorption featuring small lesions, and grayish-yellow, fragile, infiltrated, inflammatory pulmonary tissue. In B6, no discernible tumor infiltration or destruction in the central branches examined. Immediately next to the tumor there is an inflammatory, adherent section of lung (from the middle pulmonary lobe?), closed in by the base clip, measuring 15 mm, and without any discernible tumor infiltration. Other than the tumorous and pneumonic infiltration on laminated sections, no further focal findings.
3. L 12: bipartite, pale lymph node tissue with anthracotic pigment, measuring just under 10 mm together.
4. (a-b) L 11: segmented lymph adipose tissue with anthracotic pigment, measuring 25 mm together, also displaying blood coagulation in between (complete embedment).
5. (a-b) L 9: bipartite lymph adipose tissue, measuring just under 20 mm together. Nodes with anthracotic pigment and unremarkably imposing (complete embedment).
6. L7: bipartite lymph adipose tissue, measuring 10 mm together
7. L 4: node with anthracotic pigment and adipose tissue, measuring 10 mm.
8. L 3: adipose tissue measuring 10 mm, with an unremarkable node measuring 5 mm and with anthracotic pigment.

Microscopic findings:

1. (HE) In the instantaneous section and the subsequent paraffin embedment, pleura biopsy with knotty sclerohyalinosis with slit-shaped dehiscences between the thickened, collagen fiber bundles. Base lymphoid infiltration and slight subpleural adipose connective tissue.
2. (HE, f: PAS, e to h: EvG) The central bronchial amputation border has a bronchial wall with a regular structure, as does the peribronchial soft tissue. Next to this and further towards the central and hilar section there are lymph nodes with anthracotic pigment build-up and moderate histiocytosis as well as slightly lymphatic hyperplasia and small scarred areas. The tumor described comprises mesh-like infiltrative, growing structures of a pluriform, partly keratinizing, partly severe pleomorphic cell and squamous cell carcinoma with a clearly misaligned nucleoplasmic ratio, coarsening of the chromatin and prominent nucleoli and frequent mitosis. Extensive necrosis in the center of the tumor, with pseudocystic transformation, with concomitant stromadesmoplasia and lymphoid and lymphofollicular infiltrates in the tumor periphery. Extension to the perifocal, reactive, fibrosed pleura with fibrinous exudate which is no longer fresh; the base membrane of the pleura, with fragmented, elastic membrane here, is, however, not infiltrated. Hemangioid invasion in the tumor center with a formation of obliterative tumor thrombi. Next to the tumor there are several confluent alveolar cavities with a build-up of granulocytes and foam cell macrophages, fibrinous exudate and finally confluent, sprouting mesenchyme buds as well as expanded bronchia with mucus permeated by a large quantity of leucocytes.

[page 2 of 2]
3. (HE) Tumor-free lymph node tissue with lymphofollicular hyperplasia, with activated germinal centers, sinus histiocytosis and marked anthracosis.

4. Similar to 3

5. Similar to 3

6. Similar to 3

7. Similar to 3

8. Similar to 3

Diagnosis:

Resected left inferior lobe 1. to 8. with a centrally postnecrotically-pseudocystically transformed, poorly differentiated and focal, keratinizing, maturing squamous cell carcinoma, measuring a maximum of 40 mm, and located in the periphery of S 6. It extends to the still tumor-free, reactive, thickened pleura. The lobe also displays hemoangioinvasion, and, in the peritumorous section, partly purulent, partly xanthomatous retention pneumonia, and a tumor-free bronchial resection margin, as well as adjacent and hilar tumor-free lymph nodes with anthracotic pigment. In samples 3 to 8 there are further tumor-free lymph nodes with anthracotic pigment and parietal pleura with a small build-up of hyaline plaque.

Tumor classification:

M-8071/3, G3, pT2, pV 1, pN 0, pMX, stage I B. R 0.

Source: NCI Genomic Data Commons file 19a2747d-ddd2-47ce-a051-7a427d7d053c (TCGA-66-2753.E430D6D9-D03A-437B-9045-18EA0DE16574.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).